Somatic mutation profile of tumor specimen ALCH-AES0-TTP1-A (aliquot ALCH-AES0-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AES0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 83.4 years (30,467 days).
Specimen ALCH-AES0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 088f5e8c-b5dc-400b-ab81-16424d6d6962.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AES0-NB1-A (Blood Derived Normal), aliquot ALCH-AES0-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20e9499c-3f0d-4f53-aae3-ae2951e2ad0f

The open-access MAF lists 24 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 4, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8009C>T p.S2670L | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359035, CD1414729, CM043983, CM065037, COSV66453386; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2
- GNAQ | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 20/162 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs753716491, COSV54106107; called by muse, varscan2
- TMEM59L | c.1028A>G p.*343Wext*20 | Nonstop Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs1349370401; called by muse, mutect2
- ARHGAP19 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); called by muse, mutect2
- CHD7 | c.3095A>G p.E1032G | Missense Mutation (SNP) | VAF 14/467 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- FOXR2 | c.529A>T p.S177C | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- H3-3A | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 12/277 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- IQGAP2 | c.2756T>C p.I919T | Missense Mutation (SNP) | VAF 15/384 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2
- PSKH1 | c.228A>T p.E76D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- TERB1 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2
- TRPA1 | c.1474A>C p.N492H | Missense Mutation (SNP) | VAF 16/551 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- TRPC6 | c.2750G>T p.G917V | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); called by muse, mutect2
- VN1R4 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 17/335 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.169); called by muse, mutect2
- DEPDC1 | c.1956A>G p.R652= (on ENST00000456315 / NM_001114120.3; = p.R368= on NM_017779.6) | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- ERCC6 | c.870T>C p.C290= | Silent (SNP) | VAF 40/763 reads (5%) | called by muse, mutect2
- ESYT3 | c.571C>T p.L191= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- FSCB | c.576T>A p.A192= | Silent (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- PKHD1 | c.8040A>T p.P2680= | Silent (SNP) | VAF 20/283 reads (7%) | catalogued as COSV100585108; called by muse, mutect2
- TTN | c.43005C>A p.V14335= (on ENST00000591111; = p.V6911= on NM_003319.4) | Silent (SNP) | VAF 48/798 reads (6%) | called by muse, mutect2
- BCAR4 | n.876A>G | RNA (SNP) | VAF 4/52 reads (8%) | catalogued as rs1440175130; called by muse, mutect2
- CIT | c.3714+12T>C | Intron (SNP) | VAF 14/322 reads (4%) | called by muse, mutect2
- GFER | c.455+24G>C | Intron (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- HSD3B7 | c.432-31C>G | Intron (SNP) | VAF 10/266 reads (4%) | called by muse, mutect2
- PPP2R5C | c.94-21749C>T | Intron (SNP) | VAF 18/275 reads (7%) | catalogued as rs1054174909; called by muse, mutect2
